Surgical pathology report (de-identified scan), TCGA case TCGA-06-0125, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0125-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSIS:

LEFT TEMPORAL LOBE, BIOPSY: GLIOBLASTOMA MULTIFORME (MIB-1: 30%).

Operation/Specimen: Frozen section tube (sent); left temporal tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

A. Multiple 0.2-0.5 cm tissue fragments. Frozen section diagnosis:
Glioma. In # 1-3.

B.

SPECIMEN: Left temporal tumor.

FIXATIVE: Formalin.

GENERAL: A 2 x 1.8 x 0.8 cm. aggregate of pink-tan rubbery
lobulated soft tissue.

SECTIONS: X1 - all submitted.
[REDACTED]

MICROSCOPIC: A,B. Sections show a high grade glioma with high
cellular density, nuclear pleomorphism, mitotic figures, vesicular
proliferation and multiple foci of pseudopalisading necrosis.
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 0003c831-a4f6-47f4-8400-caedf42ccf3c (TCGA-06-0125.E2760AAE-ED41-402F-A777-7B1D7F50E52E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).